FM case AD13881 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms.
https://portal.gdc.cancer.gov/cases/0e33812c-583b-4309-81a4-64509accc98f

Male, 26.6 years: Myoepithelial carcinoma (ICD-O-3 8982/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
